Somatic mutation profile of tumor specimen C3N-02926-01 (aliquot CPT0184600007) from CPTAC case C3N-02926, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 50.5 years (18,463 days).
Specimen C3N-02926-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c688562-f20c-42a3-9f68-07496613d058.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02926-31 (Blood Derived Normal), aliquot CPT0184660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e925f0e-ea3d-4f54-b8fd-d5ef03625dc2

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Intron 2, Splice Site 2, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 114/504 reads (23%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.994-2A>T p.X332_splice | Splice Site (SNP) | VAF 147/302 reads (49%) | hotspot (GDC flag); catalogued as CS159286, COSV52692098, COSV52692518, COSV53122371; called by muse, mutect2, varscan2
- CNTN2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs199539011; called by muse, mutect2, varscan2
- DIDO1 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV56614074; called by muse, mutect2, varscan2
- GPRC5B | c.674A>T p.K225M | Missense Mutation (SNP) | VAF 22/577 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026997, COSV56029018; called by muse, mutect2
- GSDME | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 154/457 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs770265619, COSV61653088; called by muse, mutect2, varscan2
- MUC12 | c.5635G>A p.G1879S (on ENST00000379442; = p.G1736S on NM_001164462.1) | Missense Mutation (SNP) | VAF 137/1328 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs1481467653; called by muse, varscan2
- MUC12 | c.14134G>A p.G4712S (on ENST00000379442; = p.G4569S on NM_001164462.1) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); catalogued as rs1186165923; called by mutect2, varscan2
- SPTAN1 | c.3530G>A p.G1177D | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV63987310; called by muse, mutect2
- ASTL | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CFAP54 | c.4346C>A p.A1449E | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- DDX19A | c.801C>G p.C267W | Missense Mutation (SNP) | VAF 115/203 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FGF14 | c.361A>T p.T121S | Missense Mutation (SNP) | VAF 14/347 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.075); called by muse, mutect2
- LRFN5 | c.47A>T p.K16I | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2
- NDRG4 | c.217C>A p.Q73K (on ENST00000570248 / NM_001378344.1; = p.Q105K on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2
- NEK4 | c.1889_1894+8del p.X630_splice | Splice Site (DEL) | VAF 37/133 reads (28%) | called by mutect2, pindel, varscan2
- PIDD1 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PIK3R4 | c.2577G>T p.W859C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RNF17 | c.4727C>T p.A1576V | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- SLC4A3 | c.2489T>C p.L830P | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLK4 | c.936C>G p.R312= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV100309160; called by muse, mutect2, varscan2
- KCNJ4 | c.858C>T p.I286= | Silent (SNP) | VAF 102/353 reads (29%) | catalogued as rs757723128, COSV57857452; called by muse, mutect2, varscan2
- LGI1 | c.636T>C p.N212= | Silent (SNP) | VAF 71/190 reads (37%) | called by muse, mutect2, varscan2
- NT5C1A | c.879C>G p.L293= | Silent (SNP) | VAF 21/329 reads (6%) | called by muse, mutect2
- OR6C65 | c.468C>T p.P156= | Silent (SNP) | VAF 63/191 reads (33%) | catalogued as COSV65569774; called by muse, mutect2, varscan2
- POM121C | c.2586C>T p.G862= (on ENST00000607367; = p.G620= on NM_001099415.3) | Silent (SNP) | VAF 152/1499 reads (10%) | called by muse, mutect2, varscan2
- REN | c.27C>T p.R9= | Silent (SNP) | VAF 166/605 reads (27%) | called by muse, mutect2, varscan2
- TSHZ3 | c.720C>T p.R240= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs760381593; called by muse, mutect2, varscan2
- CHCHD2P9 | n.2T>C | RNA (SNP) | VAF 48/168 reads (29%) | called by muse, mutect2, varscan2
- FKBP6 | c.57+26G>A | Intron (SNP) | VAF 14/514 reads (3%) | catalogued as rs1253125719; called by muse, mutect2
- PEX19 | c.71-498G>C | Intron (SNP) | VAF 48/203 reads (24%) | called by muse, mutect2, varscan2
- RAB40C | chr16:629754 C>G | 3'Flank (SNP) | VAF 116/255 reads (45%) | called by muse, mutect2, varscan2
